Somatic mutation profile of tumor specimen C3L-00625-02 (aliquot CPT0081470007) from CPTAC case C3L-00625, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 34.9 years (12,736 days).
Specimen C3L-00625-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caccd32b-563b-4fcd-949b-22a91cf4bf4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00625-31 (Blood Derived Normal), aliquot CPT0081510001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2906c511-e6d3-439b-845b-b2a13ccd5bed

The open-access MAF lists 34 somatic variants for this specimen: 16 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 12, 5'UTR 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 56/330 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1H | c.4436G>A p.R1479H | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs776023990, COSV62000838; called by muse, mutect2, varscan2
- CLCN7 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 56/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213940371; called by muse, mutect2, varscan2
- DNAH6 | c.6865G>A p.A2289T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs528704325, COSV52859804; called by muse, mutect2, varscan2
- LCP2 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs752977011, COSV50455905, COSV99252348; called by muse, mutect2, varscan2
- RYR3 | c.6233G>C p.G2078A | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV66776470; called by muse, mutect2, varscan2
- CCT6A | c.901T>C p.S301P | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- CNR1 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESYT3 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 81/513 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPH2 | c.634A>T p.R212W | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT7 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- METRNL | c.546C>A p.H182Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.78); called by muse, varscan2
- PDP2 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKCQ | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- RPL18 | c.388T>C p.S130P | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- SNRNP200 | c.5732A>T p.D1911V | Missense Mutation (SNP) | VAF 74/425 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ASXL3 | c.6468A>C p.T2156= | Silent (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- BEND4 | c.627C>T p.N209= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs574971489, COSV72468915; called by muse, mutect2, varscan2
- DNAH11 | c.9666G>A p.V3222= | Silent (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- FCGR2C | c.600C>A p.G200= | Silent (SNP) | VAF 30/359 reads (8%) | catalogued as rs1262663657; called by muse, varscan2
- H2AC11 | c.267C>T p.R89= | Silent (SNP) | VAF 31/409 reads (8%) | called by muse, mutect2
- INPPL1 | c.1599C>T p.G533= | Silent (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- ITCH | c.1155G>A p.T385= (on ENST00000262650 / NM_001257137.3; = p.T344= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/400 reads (29%) | catalogued as rs201221876; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEU4 | c.39C>T p.F13= (on ENST00000391969 / NM_001167602.3; = p.F25= on NM_080741.4) | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as rs920176159, COSV57990448; called by muse, mutect2, varscan2
- NME8 | c.312G>A p.P104= | Silent (SNP) | VAF 52/302 reads (17%) | catalogued as rs536359204, COSV52246470; ClinVar: likely benign; called by muse, mutect2, varscan2
- RGS12 | c.1782G>A p.P594= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs751083722; called by muse, mutect2, varscan2
- SLITRK3 | c.2892G>A p.P964= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs781561672, COSV53850899, COSV99578396; called by muse, varscan2
- WDR97 | c.987C>T p.F329= | Silent (SNP) | VAF 41/262 reads (16%) | called by muse, mutect2, varscan2
- CLDN16 | c.-96C>G | 5'UTR (SNP) | VAF 53/325 reads (16%) | called by muse, mutect2, varscan2
- MMGT1 | c.-252C>G | 5'UTR (SNP) | VAF 60/466 reads (13%) | called by muse, mutect2, varscan2
- PDGFD | c.125-36588G>A | Intron (SNP) | VAF 34/140 reads (24%) | catalogued as rs777102812, COSV56395204; called by muse, mutect2
- PRKAG3 | c.775-12C>T | Intron (SNP) | VAF 75/466 reads (16%) | catalogued as rs753669652; called by muse, mutect2, varscan2
- UBBP4 | n.537G>A | RNA (SNP) | VAF 88/600 reads (15%) | called by muse, mutect2, varscan2
- VAMP3 | c.-38C>A | 5'UTR (SNP) | VAF 45/261 reads (17%) | called by muse, mutect2, varscan2
